TCGA case TCGA-38-4632 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: UNC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/875333ab-9048-462d-aaa2-693ad127e3cc

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 42 years; Vital status: Dead; Days to death: 1,357 days (3.7 years).

Diagnoses (3)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 42.2 years (15,418 days); Year of diagnosis: 1998; AJCC staging edition: 5th; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Peripheral Lung.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 35 days; Days to treatment end: 70 days; Treatment dose: 5,800 cGy; Treatment outcome: Complete Response; Number of fractions: 22; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine + Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 679 days (1.9 years); Days to treatment end: 802 days (2.2 years); Number of cycles: 6; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Palliative; Days to treatment start: 955 days (2.6 years); Days to treatment end: 955 days (2.6 years); Treatment dose: 2,500 cGy; Course number: 3; Number of fractions: 10; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan Hydrochloride; Treatment intent type: Palliative; Days to treatment start: 1,127 days (3.1 years); Days to treatment end: 1,169 days (3.2 years); Number of cycles: 2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Palliative; Days to treatment start: 1,136 days (3.1 years); Days to treatment end: 1,169 days (3.2 years); Number of cycles: 2; Route of administration: Intravenous.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 44.1 years (16,098 days); Days to diagnosis: 680 days (1.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 44.7 years (16,343 days); Days to diagnosis: 925 days (2.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Distant Site; Surgery, NOS to Locoregional Site.

Follow-up (3 entries)
- Day 680 (post initial treatment): Progression or recurrence: Yes.
- Day 925 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 1,357 days (3.7 years); Disease response: With Tumor.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 10; Tobacco smoking quit year: 1991.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-38-4632-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.7; Shortest dimension: 0.3.
  Slide TCGA-38-4632-01A-01-TS1: Section location: Top; Percent tumor cells: 88; Percent tumor nuclei: 70; Percent normal cells: 5; Percent necrosis: 2; Percent stromal cells: 5.
  Slide TCGA-38-4632-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 70; Percent normal cells: 10; Percent necrosis: 10; Percent stromal cells: 5.
- Sample TCGA-38-4632-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-38-4632-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.6; Intermediate dimension: 1; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 4; Anatomic organ subdivision: L-Upper; Location lung parenchyma: Peripheral Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: No.
- Drug treatment 1: Regimen number: LCCC 9831; Therapy regimen: Recurrence.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 3.
- Drug treatment 4: Regimen number: 3; Pharmaceutical therapy drug name: CPT-11.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No; Treatment outcome at TCGA followup: Stable Disease.
- Follow-up form 2: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No; Treatment outcome at TCGA followup: Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,357 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,357 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 680 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-38-4632-01A-01D-1752-01): tumor purity 0.37, ploidy 3.86, whole-genome doublings 1.
